Somatic mutation profile of tumor specimen 0DJTFR from CCDI case PBBXMV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.7 years (987 days).
Specimen 0DJTFR: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e68b9ce8-5922-402d-9f70-e10b1f42a03e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DJTG0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be1f422b-527b-4a2c-bc4b-67a775da7f57

The open-access MAF lists 27 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 6, Nonsense Mutation 4, 5'UTR 2, Intron 2, Frame Shift Del 2, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 427/501 reads (85%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.383); catalogued as rs104894229, CM053283, CM061797, COSV54236795, COSV54236828, COSV54237299; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.946G>T p.E316* (on ENST00000281708 / NM_001349798.2; = p.E236* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 384/1203 reads (32%) | catalogued as COSV99655455; called by muse, mutect2, varscan2
- IGSF10 | c.6634G>A p.V2212I | Missense Mutation (SNP) | VAF 144/675 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.607); catalogued as rs767907919, COSV99196332; called by muse, mutect2, varscan2
- NALCN | c.3237G>T p.E1079D | Missense Mutation (SNP) | VAF 295/1448 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as COSV99216287, COSV99217658; called by muse, mutect2, varscan2
- PLXNB3 | c.1027G>A p.G343S | Missense Mutation (SNP) | VAF 98/411 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.689); catalogued as rs1434738521; called by muse, mutect2, varscan2
- PPP4C | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 33/528 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as rs1178701945; called by muse, mutect2
- RNF220 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 172/460 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1409456916, COSV59191244; called by muse, mutect2, varscan2
- FARP2 | c.1930C>A p.L644I | Missense Mutation (SNP) | VAF 220/949 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- GAGE10 | c.300del p.P101Qfs*4 | Frame Shift Del (DEL) | VAF 95/384 reads (25%) | called by mutect2, varscan2
- IGFBP6 | c.603C>A p.C201* | Nonsense Mutation (SNP) | VAF 51/283 reads (18%) | called by muse, mutect2, varscan2
- MUC5B | c.6251del p.T2084Kfs*7 | Frame Shift Del (DEL) | VAF 72/342 reads (21%) | called by mutect2, varscan2
- NF1 | c.6412C>T p.Q2138* (on ENST00000358273 / NM_001042492.3; = p.Q2117* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 55/725 reads (8%) | called by muse, mutect2
- PUDP | c.604_610dup p.T204Rfs*27 | Frame Shift Ins (INS) | VAF 134/757 reads (18%) | called by mutect2, varscan2
- RELCH | c.2378C>T p.P793L | Missense Mutation (SNP) | VAF 271/903 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- RNF17 | c.4773+1G>A p.X1591_splice | Splice Site (SNP) | VAF 107/679 reads (16%) | called by muse, mutect2, varscan2
- SEMA5A | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 175/644 reads (27%) | called by muse, mutect2, varscan2
- ZNF573 | c.-22-1G>A | Splice Site (SNP) | VAF 87/264 reads (33%) | called by muse, mutect2, varscan2
- CERS5 | c.558G>A p.G186= | Silent (SNP) | VAF 143/536 reads (27%) | called by muse, mutect2, varscan2
- MXRA5 | c.2124G>A p.E708= | Silent (SNP) | VAF 395/841 reads (47%) | catalogued as COSV99476482; called by muse, mutect2, varscan2
- OGDH | c.2112C>T p.N704= | Silent (SNP) | VAF 156/720 reads (22%) | called by muse, mutect2, varscan2
- TNR | c.1014C>T p.S338= | Silent (SNP) | VAF 157/587 reads (27%) | catalogued as rs779406233, COSV54891052; called by muse, mutect2, varscan2
- USP51 | c.1659A>G p.L553= | Silent (SNP) | VAF 177/826 reads (21%) | called by muse, mutect2, varscan2
- ZNF443 | c.1845G>A p.P615= | Silent (SNP) | VAF 262/1072 reads (24%) | catalogued as rs767987589, COSV56890597, COSV56891302; called by muse, mutect2, varscan2
- DGKD | c.1194+44G>A | Intron (SNP) | VAF 67/276 reads (24%) | catalogued as rs371106768; called by muse, mutect2, varscan2
- KLHL3 | c.1451-65C>A | Intron (SNP) | VAF 54/138 reads (39%) | called by muse, mutect2, varscan2
- RNASEH1 | c.-30C>T | 5'UTR (SNP) | VAF 17/196 reads (9%) | catalogued as rs774009217; called by muse, mutect2
- SNX3 | c.-42G>C | 5'UTR (SNP) | VAF 57/148 reads (39%) | called by muse, mutect2, varscan2
